Somatic mutation profile of tumor specimen TCGA-55-6971-01A (aliquot TCGA-55-6971-01A-11D-1945-08) from TCGA case TCGA-55-6971, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.5 years (21,734 days).
Specimen TCGA-55-6971-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8383e3da-c1df-4780-979f-bc58e1322345.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6971-11A (Solid Tissue Normal), aliquot TCGA-55-6971-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99eeb9be-e2d0-48e3-9940-daf1aee705e4

The open-access MAF lists 87 somatic variants for this specimen: 70 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 14, Nonsense Mutation 8, Splice Site 3, Frame Shift Del 3, RNA 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1065+1G>C p.X355_splice | Splice Site (SNP) | VAF 7/41 reads (17%) | catalogued as rs201089102, COSV53780484; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV61616139; called by muse, mutect2, varscan2
- ADGRV1 | c.12409G>T p.A4137S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV67996852; called by muse, varscan2
- ANO3 | c.146G>C p.S49T | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.024); catalogued as COSV56811786, COSV99886479; called by muse, mutect2, varscan2
- ARID4A | c.2745A>G p.I915M | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.201); catalogued as COSV62165628, COSV62167049; called by muse, mutect2, varscan2
- ASS1 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV61691010; called by muse, mutect2, varscan2
- CACNA1C | c.2288C>T p.T763I | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59781939; called by muse, mutect2, varscan2
- CMTM5 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs201547213, COSV100197917; called by mutect2, varscan2
- COL4A6 | c.2833+1G>T p.X945_splice | Splice Site (SNP) | VAF 19/95 reads (20%) | catalogued as COSV57881109; called by muse, mutect2, varscan2
- CUEDC1 | c.218A>T p.N73I | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100804828; called by muse, mutect2
- DARS1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs370064817, CM133672, CM150753, COSV51542405; called by muse, mutect2, varscan2
- DPY19L2 | c.757A>T p.N253Y | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1428909063, COSV60546384; called by muse, mutect2, varscan2
- DPY19L4 | c.1624T>C p.W542R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV68964001; called by muse, mutect2, varscan2
- EFTUD2 | c.2576A>T p.Q859L | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV53656507; called by muse, mutect2
- F8 | c.3944G>A p.R1315K | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV64279622; called by muse, mutect2
- FAM47A | c.1213A>G p.K405E | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.042); catalogued as COSV60500387; called by muse, mutect2, varscan2
- FMR1NB | c.668G>T p.R223I | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV65073292; called by muse, mutect2, varscan2
- GBGT1 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs1308573408, COSV100923801; called by muse, varscan2
- GCN1 | c.3073G>A p.G1025R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV56107703; called by muse, varscan2
- INTS6L | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66083911; called by muse, mutect2, varscan2
- ITSN2 | c.1962C>A p.Y654* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as COSV61954905; called by muse, mutect2, varscan2
- JCAD | c.2060G>C p.R687T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64762100; called by muse, mutect2, varscan2
- KLK11 | c.761A>T p.D254V (on ENST00000594768 / NM_144947.3; = p.D222V on NM_006853.3) | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.165); catalogued as COSV59399801; called by muse, mutect2
- LCP2 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1440505024, COSV50458944, COSV50471373; called by muse, mutect2, varscan2
- MAP2 | c.4048G>T p.A1350S | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52311447; called by muse, mutect2, varscan2
- MCF2 | c.587T>A p.V196E | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100644772, COSV58496570; called by muse, mutect2, varscan2
- MCOLN2 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs1355532301, COSV52300192; called by muse, mutect2, varscan2
- MEIS2 | c.100C>T p.P34S (on ENST00000561208 / NM_170675.5; = p.P21S on NM_002399.3) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs1289568511, COSV54939040; called by muse, mutect2, varscan2
- MMGT1 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60004421; called by muse, mutect2, varscan2
- MROH2B | c.2128C>A p.L710I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.782); catalogued as COSV68190403; called by muse, mutect2, varscan2
- MYO3B | c.1178C>A p.S393Y | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58720787; called by muse, mutect2, varscan2
- NF1 | c.6675G>A p.W2225* (on ENST00000358273 / NM_001042492.3; = p.W2204* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as CM1411402, COSV62224628; called by muse, mutect2, varscan2
- NLRP12 | c.1103C>A p.A368E | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.263); catalogued as rs1466281918, COSV60756937; called by muse, mutect2, varscan2
- NMUR2 | c.654G>T p.Q218H | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54923435; called by mutect2, varscan2
- NTHL1 | c.868T>G p.C290G (on ENST00000219066; = p.C282G on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54594618, COSV99526171; called by muse, mutect2, varscan2
- OR2L13 | c.378C>A p.C126* | Nonsense Mutation (SNP) | VAF 26/298 reads (9%) | catalogued as COSV63563000; called by muse, mutect2
- OR2T1 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV63543054; called by muse, mutect2, varscan2
- OR4Q3 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV59179335, COSV59180708; called by muse, mutect2, varscan2
- OR8I2 | c.519C>G p.I173M | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56171009; called by muse, varscan2
- PHIP | c.4469A>G p.N1490S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs759078097, COSV51512003; called by muse, mutect2, varscan2
- PIK3C2B | c.1035-1G>A p.X345_splice | Splice Site (SNP) | VAF 12/70 reads (17%) | catalogued as rs1247214715, COSV65804318; called by muse, mutect2, varscan2
- PIM2 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV55946758; called by muse, mutect2, varscan2
- PLAG1 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated, low confidence (0.94); PolyPhen possibly damaging (0.811); catalogued as COSV57616395; called by muse, mutect2
- PLXNA2 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV65445801; called by mutect2, varscan2
- PLXNA2 | c.398A>T p.Y133F | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.462); catalogued as rs749758154, COSV65445807; called by muse, mutect2, varscan2
- PRELID3A | c.107T>A p.V36E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61254481; called by muse, mutect2
- PSME4 | c.2141A>T p.Y714F | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV66368458; called by muse, mutect2, varscan2
- PTPN4 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.744); catalogued as COSV55310408; called by muse, mutect2, varscan2
- PTPRF | c.3406G>T p.V1136L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63449783; called by muse, mutect2, varscan2
- RSPH9 | c.188T>A p.L63Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV100937880; called by muse, mutect2, varscan2
- SDCCAG8 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59406879, COSV59419250; called by muse, mutect2, varscan2
- SLC2A10 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as COSV63716260; called by muse, mutect2, varscan2
- SLC35B4 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65985658; called by muse, mutect2, varscan2
- SLCO1B1 | c.1366C>A p.L456I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as COSV57018612; called by muse, mutect2, varscan2
- SYT10 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 32/195 reads (16%) | catalogued as COSV57346533; called by muse, mutect2, varscan2
- TBC1D9 | c.2204del p.G735Efs*4 | Frame Shift Del (DEL) | VAF 35/234 reads (15%) | catalogued as COSV71307230, COSV71307440; called by mutect2, pindel, varscan2
- TET1 | c.4778G>A p.S1593N | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV65384230, COSV65390202; called by muse, mutect2, varscan2
- TMEM200A | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV51660963; called by muse, mutect2, varscan2
- TNKS2 | c.2446A>T p.R816* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV65417231; called by muse, mutect2, varscan2
- TSHZ3 | c.2923G>T p.V975F | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53665907, COSV53685439; called by muse, mutect2, varscan2
- UTRN | c.3659G>A p.R1220K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV62350013; called by muse, mutect2, varscan2
- YTHDC2 | c.462T>A p.F154L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV50756992; called by muse, mutect2, varscan2
- ZFAT | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV64748846; called by muse, mutect2, varscan2
- ZNF235 | c.1526A>T p.H509L | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52158793; called by muse, mutect2
- ZNF615 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 23/169 reads (14%) | catalogued as rs1250910244, COSV100944040; called by muse, varscan2
- ZNF644 | c.2891C>A p.S964* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100494801; called by muse, mutect2, varscan2
- DNAH9 | c.6663del p.K2222Sfs*9 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel*, varscan2
- LRRN2 | c.2030del p.P677Lfs*75 | Frame Shift Del (DEL) | VAF 10/116 reads (9%) | called by mutect2, pindel
- TRBV4-1 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TRPV5 | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); called by muse, mutect2
- ABCA9 | c.3912G>A p.K1304= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV60632237; called by muse, mutect2, varscan2
- ARHGAP36 | c.1563C>T p.P521= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV52273358; called by muse, mutect2, varscan2
- BBOX1 | c.711G>T p.V237= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99590100; called by mutect2, varscan2
- CHD7 | c.7884T>C p.H2628= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as CD061381, COSV71115406; called by muse, mutect2, varscan2
- CPVL | c.1305G>T p.A435= | Silent (SNP) | VAF 39/264 reads (15%) | catalogued as rs780931131, COSV55302957, COSV55309725; called by muse, mutect2, varscan2
- DAW1 | c.621G>A p.Q207= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV59369841; called by muse, mutect2, varscan2
- ERCC6L | c.1770A>G p.V590= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV57822673; called by muse, mutect2, varscan2
- FBXO10 | c.300A>G p.L100= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs753714562, COSV52836261; called by muse, mutect2, varscan2
- HPSE2 | c.1173C>T p.N391= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV65204153; called by mutect2, varscan2
- HYDIN | c.12153C>T p.F4051= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV66642903; called by mutect2, varscan2
- MAP3K10 | c.915G>A p.E305= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV53425810; called by muse, mutect2, varscan2
- MITF | c.696A>G p.L232= (on ENST00000448226 / NM_006722.3; = p.L126= on NM_000248.4) | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV58836696; called by mutect2, varscan2
- OR6B1 | c.459T>C p.F153= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV68770700; called by muse, mutect2, varscan2
- WNK3 | c.216C>A p.A72= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as COSV63615560, COSV63616304; called by muse, mutect2, varscan2
- TUBB4AP1 | n.499C>A | RNA (SNP) | VAF 9/75 reads (12%) | called by mutect2, varscan2
- XIST | n.8321C>G | RNA (SNP) | VAF 8/36 reads (22%) | catalogued as rs1214380497; called by muse, mutect2, varscan2
- ZNF584 | c.292+197G>T | Intron (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100183466; called by mutect2, varscan2
